Surgical pathology report (de-identified scan), TCGA case TCGA-28-5218, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Cedars Sinai, specimen TCGA-28-5218-01A (Primary Tumor).

[page 1 of 5]
Patient: [REDACTED]

Accession Number: [REDACTED]

Hospital No: [REDACTED]

Pathologist: [REDACTED]

Ordering M.D.: [REDACTED]

Date of Birth: [REDACTED]

Assistant: [REDACTED]

Age/Sex: [REDACTED]

Date of Procedure: [REDACTED]

Copies To: [REDACTED]

Date Received: [REDACTED]

Location: [REDACTED]

TCGA-28-5218

SURGICAL PATHOLOGY REPORT

***** Addendum - Please See End of Report *****

Reason for Addendum #1: Additional studies/stains/opinion(s)

Reason for Addendum #2: Additional studies/stains/opinion(s)

DIAGNOSIS: [REDACTED]

A. BRAIN, RIGHT TEMPORAL, EXCISIONAL BIOPSY:

- Necrotic amorphous debris

B. BRAIN, RIGHT TEMPORAL, BIOPSY, NCI #1:

- Malignant neoplasm, most consistent with gliosarcoma, WHO grade IV
- 0% of tumor necrosis
- 95% of tumor cellularity

C. BRAIN, RIGHT TEMPORAL, BIOPSY, NCI #2:

- Malignant neoplasm, most consistent with gliosarcoma, WHO grade IV
- Unremarkable choroid plexus
- 0% of tumor necrosis
- 70% of tumor cellularity

D. BRAIN, RIGHT TEMPORAL, BIOPSY, NCI #3:

- Malignant neoplasm, most consistent with gliosarcoma, WHO grade IV
- 50% of tumor necrosis
- 90% of tumor cellularity

E. BRAIN, RIGHT TEMPORAL, BIOPSY, NCI #4:

- Malignant neoplasm, most consistent with gliosarcoma, WHO grade IV
- 5% of tumor necrosis
- 95% of tumor cellularity

F. BRAIN, RIGHT TEMPORAL, BIOPSY, NCI #5:

- Malignant neoplasm, most consistent with gliosarcoma, WHO grade IV
- 20% of tumor necrosis
- 95% of tumor cellularity

G. BRAIN, RIGHT TEMPORAL, BIOPSY:

- Malignant neoplasm, most consistent with gliosarcoma, WHO grade IV

H. BRAIN, RIGHT TEMPORAL, POSSIBLE CLINICAL TRIAL, EXCISIONAL BIOPSY:

- Malignant neoplasm, most consistent with gliosarcoma, WHO grade IV

I. BRAIN, RIGHT TEMPORAL, EXCISIONAL BIOPSY:

- Malignant neoplasm, most consistent with gliosarcoma, WHO grade IV

J. BRAIN, RIGHT TEMPORAL, EXCISIONAL BIOPSY:

- Malignant neoplasm, most consistent with gliosarcoma, WHO grade IV

Patient Case(s) [REDACTED]

Copy For: [REDACTED]

Page 1 of 7

PATIENT NOTIFIED OF RESULTS
DR: _____ NURSE: _____ DATE: _____

[page 2 of 5]
PATIENT:

***** Addendum - Please See End of Report *****

ACCESSION #:

Slide key:

B1. 1

C. RIGHT TEMPORAL NCI #2

Labeled with the patient's name, labeled "right temporal NCI", and received in formalin is a 1.0 x 0.5 x 0.2 cm portion of soft tan-white tissue. Entirely submitted.

Slide key:

C1. 1

D. RIGHT TEMPORAL NCI #3

Labeled with the patient's name, labeled "right temporal NCI", and received in formalin is a 1.1 x 0.6 x 0.2 cm portion of soft tan-white focally hemorrhagic tissue. Entirely submitted.

Slide key:

D1. 1

E. RIGHT TEMPORAL NCI #4

Labeled with the patient's name, labeled "right temporal NCI", and received in formalin is a 0.8 x 0.8 x 0.2 cm portion of tan-white soft tissue. Entirely submitted.

Slide key:

E1. 1

F. RIGHT TEMPORAL NCI #5

Labeled with the patient's name, labeled "right temporal NCI", and received in formalin is a 1.3 x 0.7 x 0.2 cm portion of tan-white soft tissue. Entirely submitted.

Slide key:

F1. 1

G. RIGHT TEMPORAL FROZEN SECTION #2

Labeled with the patient's name, labeled "right temporal frozen section #2", and received in formalin are multiple aggregates of soft tan-white and hemorrhagic tissues aggregating to 3.0 x 1.5 x 0.2 cm and ranging from 0.3 to 1.5 cm in greatest dimension. Entirely submitted.

Slide key:

G1. Frozen section remnant - 1

G2. Multiple

H. RIGHT TEMPORAL CLINICAL TRIAL

Labeled with the patient's name, labeled "right temporal clinical trial", and received in formalin is a 1.2 x 1.2 x 0.8 cm portion of tan-white and focally hemorrhagic tissue. Entirely submitted.

Slide key:

H1. 1

H2. 1

I. RIGHT TEMPORAL EM

Labeled with the patient's name, labeled "right temporal EM", and received in Zeus fixative are two portions of tan-yellow tissue measuring 1.0 x 0.5 x 0.2 cm and 0.5 x 0.4 x 0.2 cm, each. Entirely submitted for EM studies.

[page 3 of 5]
***** Addendum - Please See End of Report *****

PATIENT: [REDACTED]

ACCESSION #: [REDACTED]

J. RIGHT TEMPORAL, PERMANENT

Labeled with the patient's name, labeled "right temporal", and received in formalin is a 4.0 x 3.5 x 1.0 cm aggregate of soft tan-white and focally hemorrhagic tissue. Entirely submitted.

Slide key:

J1. Multiple

J2. Multiple

J3. Multiple

J4. Multiple

Gross dictated by [REDACTED]

INTRAOPERATIVE CONSULTATION:

OPERATIVE CALL

OPERATIVE CONSULT (FROZEN):

A. RIGHT TEMPORAL, FROZEN SECTION AND TOUCH PREP:

- Acellular debris

G. RIGHT TEMPORAL, FROZEN SECTION AND TOUCH PREP:

- Malignant neoplasm

I have personally examined the specimen, interpreted the results, reviewed the report and signed it electronically.

[page 4 of 5]
***** Addendum - Please See End of Report *****

PATIENT: [REDACTED]

ACCESSION #: [REDACTED]

FLUORESCENCE IN SITU HYBRIDIZATION (FISH) for EGFR in BRAIN

Tissue Block: [REDACTED]

RESULTS: POLYSOMY of chromosome 7 (See note below)

Number of cells evaluated: 40

INTERPRETATION:

Fluorescence in situ hybridization (FISH) analysis on a brain tumor sample from this patient with Abbott Molecular probes specific for the centromere of chromosome 7 (control probe) and the short arm (EGFR-7p12) of chromosome 7 was performed. The control sample gave expected results.

These studies showed polysomy of chromosome 7 in 80% of the nuclei examined. In brain tumors this signal pattern correlates with an amplified EGFR signal pattern.

NOTE:

1. Samples are considered positive in brain if the EGFR to CEP 7 signal ratio is ≥ 2.0 in $\geq 10\%$ of analyzed cells or tumors with four or more copies of the EGFR gene in $\geq 40\%$ of the cells (high polysomy).
2. Samples are considered inconclusive, requiring consult with the pathologist, in brain if the EGFR to CEP 7 signal ratio is ≥ 2.0 in $<10\%$ of analyzed cells or when four or more copies of the EGFR gene in $< 40\%$ of the cells.

References:

[REDACTED]

These FISH tests were developed and their performance characteristics determined by [REDACTED] as required by the CLIA [REDACTED] regulations. They have not been cleared or approved for specific uses by the U.S. Food and Drug Administration.

I have personally examined the specimen, interpreted the results, reviewed the report and signed it electronically.

[page 5 of 5]
***** Addendum - Please See End of Report *****

PATIENT: [REDACTED]

ACCESSION #: [REDACTED]

Fluorescent in situ hybridization (FISH) for EWSR1 Disruption

RESULTS: See Comment

FISH NOMENCLATURE: nuc ish(EWSR1x2)[197/200]

COMMENT: This test is in validation and is intended for research use only. Within this limitation, no disruption of EWSR1 was identified.

Fluorescence in situ hybridization (FISH) analysis with a commercially available probe [REDACTED] that serves to identify a disruption of the EWSR1 (Ewings sarcoma region) gene located at 22q12 was carried out on 200 interphase cells. Three of the cells showed a disruption of the EWSR1 gene. This value is similar to the value obtained from a normal control. This result is consistent with the ABSENCE of the translocation involving 22q12.

I have personally examined the specimen, interpreted the results, reviewed the report and signed it electronically.

SURGICAL PATHOLOGY REPORT

If this report includes immunohistochemical test results, please note the following: Numerous immunohistochemical tests were developed and their performance characteristics determined by [REDACTED] Those immunohistochemical tests have not been cleared or approved by the U.S. Food and Drug Administration (FDA), and FDA approval is not required.

Source: NCI Genomic Data Commons file 3305fe52-9f50-43cc-96b5-2741843a0b24 (TCGA-28-5218.461DABE9-5C81-4BCE-ABD6-BA60A652094D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).